CPTAC case C3L-02504 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba4f0ba9-f184-458e-81ba-9c4b1c521336

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Dead; Days to death: 873 days (2.4 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Occipital lobe; Age at diagnosis: 71.9 years (26,277 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 873 days (2.4 years); Progression or recurrence: yes; Days to recurrence: 454 days (1.2 years); Days to last follow up: 866 days (2.4 years).
   Pathology details: Greatest tumor dimension: 1 cm.

Follow-up (3 entries)
- Days to follow up: 298 days; Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 823 days (2.3 years); Disease response: With Tumor.
- Days to follow up: 866 days (2.4 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 454 days (1.2 years).

Other clinical attributes
- Weight: 70.45 kg; Height: 167.64 cm; BMI: 25.07.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 45; Cigarettes per day: 20; Tobacco smoking onset year: 1967; Tobacco smoking quit year: 2012; Exposure duration years: 45.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02504-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 230 mg; Time between excision and freezing: 8 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02504-21: Section location: Occipital Lobe; Percent tumor nuclei: 85; Percent necrosis: 2.
- Sample C3L-02504-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 130 mg.
- Sample C3L-02504-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
